Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6570, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6570-01A (Primary Tumor).

	LARGE INTESTINE TISSUE CHECKLIST
--	----------------------------------

	Specimen type: Hemicolectomy Specimen size: Not specified Tumor site: Colon Tumor size: 9 x 8.5 x 8 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Pericolonic tissues Lymph nodes: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	---

Source: NCI Genomic Data Commons file 5b9756cc-4a15-41eb-820d-5d19a33fe053 (TCGA-F4-6570.2DB5FC84-1782-4C79-9179-11988DD8BA01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).